Somatic mutation profile of tumor specimen TCGA-3B-A9HZ-01A (aliquot TCGA-3B-A9HZ-01A-11D-A38Z-09) from TCGA case TCGA-3B-A9HZ, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of thorax; Age at diagnosis: 66.9 years (24,433 days).
Specimen TCGA-3B-A9HZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a9f278f-c916-4d27-b3dc-c254917ea4e3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3B-A9HZ-10A (Blood Derived Normal), aliquot TCGA-3B-A9HZ-10A-01D-A38Z-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cf5b9bec-dbd8-4e6c-aa3e-481bd04a5df9

The open-access MAF lists 34 somatic variants for this specimen: 20 protein-altering or splice-affecting, 10 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 10, 3'UTR 2, Splice Site 1, 3'Flank 1, Nonsense Mutation 1, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.275A>T p.D92V | Missense Mutation (SNP) | VAF 20/43 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM132264, COSV64288500, COSV64301396, COSV64302611; called by muse, mutect2, varscan2
- TP53 | c.824G>A p.C275Y | Missense Mutation (SNP) | VAF 16/34 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs863224451, CM076568, CM951234, COSV52661919, COSV52663595, COSV52675710, COSV52772708; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANAPC2 | c.749T>G p.L250R | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as COSV100118889; called by muse, mutect2, varscan2
- ATR | c.1733-1G>A p.X578_splice | Splice Site (SNP) | VAF 43/126 reads (34%) | catalogued as COSV63394629; called by muse, mutect2, varscan2
- CARD11 | c.2421G>A p.M807I | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.055); catalogued as rs1554271763, COSV100829081; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC105 | c.1058C>T p.T353M | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as rs1045428626, COSV52965988; called by muse, mutect2, varscan2
- CD163 | c.2965G>T p.G989* | Nonsense Mutation (SNP) | VAF 9/31 reads (29%) | catalogued as COSV100775658; called by muse, mutect2, varscan2
- CEP192 | c.3664G>A p.E1222K | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.037); catalogued as COSV100380579; called by muse, mutect2, varscan2
- CFH | c.811T>A p.Y271N | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.462); catalogued as COSV100661299, COSV62778634; called by muse, mutect2, varscan2
- CNOT8 | c.691T>G p.S231A | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.447); catalogued as COSV99597101; called by muse, mutect2, varscan2
- DNAH8 | c.6098C>G p.S2033C | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as rs781008225, COSV100543322; called by muse, mutect2, varscan2
- LRP2 | c.6451G>T p.A2151S | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1308597655, COSV99786556; called by muse, mutect2, varscan2
- LRRC4 | c.1847C>T p.A616V | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.529); catalogued as COSV99974745; called by muse, mutect2, varscan2
- NMNAT1 | c.562C>T p.R188W | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs761660596, CM1512287, COSV101020381; called by muse, mutect2, varscan2
- PAMR1 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as COSV53512976; called by muse, mutect2
- PFKFB4 | c.238C>T p.R80W | Missense Mutation (SNP) | VAF 39/105 reads (37%) | PolyPhen probably damaging (1); catalogued as rs201114950, COSV51682889; called by muse, mutect2, varscan2
- SEMG1 | c.1049C>G p.S350C | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.993); catalogued as COSV99725065; called by muse, mutect2, varscan2
- ST8SIA4 | c.512T>A p.L171Q | Missense Mutation (SNP) | VAF 14/40 reads (35%) | PolyPhen probably damaging (0.964); catalogued as COSV99185114; called by muse, mutect2, varscan2
- VPS35L | c.2190G>T p.Q730H | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99219640; called by muse, mutect2, varscan2
- USP31 | c.751_753del p.S251del | In Frame Del (DEL) | VAF 19/71 reads (27%) | called by mutect2, pindel, varscan2
- ADCYAP1R1 | c.276C>T p.T92= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as rs759799838, COSV100416188; called by muse, mutect2, varscan2
- ATF4 | c.96T>G p.G32= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV100307529; called by muse, mutect2, varscan2
- LRRC4 | c.1848C>A p.A616= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV99974744; called by muse, mutect2, varscan2
- MEGF10 | c.2145G>A p.T715= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as rs200994008, COSV99174715; ClinVar: likely benign; called by muse, mutect2, varscan2
- NOA1 | c.9C>G p.P3= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV99950410; called by muse, mutect2, varscan2
- OBSCN | c.17400C>T p.I5800= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV99472731; called by muse, mutect2, varscan2
- OR5T3 | c.798A>C p.T266= | Silent (SNP) | VAF 5/104 reads (5%) | catalogued as COSV100282675; called by muse, mutect2
- OTOF | c.153G>A p.P51= | Silent (SNP) | VAF 31/64 reads (48%) | catalogued as rs747514772, COSV55509081; called by muse, mutect2, varscan2
- PER2 | c.1362C>G p.A454= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as COSV99611436; called by muse, mutect2, varscan2
- RPGRIP1L | c.1524G>A p.E508= | Silent (SNP) | VAF 34/70 reads (49%) | catalogued as rs1238972011, COSV100045832; ClinVar: likely benign; called by muse, mutect2, varscan2
- CEP295 | chr11:93730520 T>G | 3'Flank (SNP) | VAF 19/95 reads (20%) | called by muse, mutect2, varscan2
- MFSD4B | c.*945G>A | 3'UTR (SNP) | VAF 14/53 reads (26%) | catalogued as COSV100920541; called by muse, varscan2
- MFSD4B | c.*1007G>A | 3'UTR (SNP) | VAF 13/59 reads (22%) | catalogued as COSV100920543; called by muse, varscan2
- RFX7 | c.-287C>T | 5'UTR (SNP) | VAF 17/67 reads (25%) | called by muse, mutect2, varscan2
